Somatic mutation profile of tumor specimen C3L-02552-02 (aliquot CPT0112580006) from CPTAC case C3L-02552, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 68.8 years (25,114 days).
Specimen C3L-02552-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a432fbc-d4ed-402d-bf8a-ba60bd241088.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02552-31 (Blood Derived Normal), aliquot CPT0115170002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6923f7c9-bbb5-4d89-a408-7e9a45672588

The open-access MAF lists 86 somatic variants for this specimen: 57 protein-altering or splice-affecting, 17 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 17, Intron 6, Nonsense Mutation 5, Translation Start Site 2, RNA 2, 3'UTR 2, 5'UTR 1, Frame Shift Del 1, Splice Site 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 34/616 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ADAMTS12 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 10/210 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs750471324; called by muse, mutect2
- ARFRP1 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 26/495 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs200507208; called by muse, mutect2
- DNMT3A | c.2216A>G p.H739R | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as COSV53087326; called by muse, mutect2
- FAT4 | c.13109C>G p.S4370C | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.724); catalogued as COSV58679798; called by muse, mutect2
- FBXO40 | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as COSV57526509; called by muse, mutect2
- FIBCD1 | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.017); catalogued as rs377608283; called by muse, mutect2
- FLG | c.6094A>G p.R2032G | Missense Mutation (SNP) | VAF 42/808 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs767747791, COSV64240965; called by muse, mutect2
- HECW2 | c.3435G>C p.E1145D | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.97); catalogued as COSV53651590; called by muse, mutect2
- HTR3B | c.1105G>T p.G369* | Nonsense Mutation (SNP) | VAF 20/234 reads (9%) | catalogued as COSV99492322; called by muse, mutect2
- LRP1B | c.10347C>A p.C3449* | Nonsense Mutation (SNP) | VAF 13/269 reads (5%) | catalogued as COSV67266413; called by muse, mutect2
- LRP1B | c.7181G>C p.G2394A | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67243933; called by muse, mutect2
- LRRC4B | c.1550C>A p.T517K | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.954); catalogued as COSV100975918; called by muse, mutect2
- NOTCH1 | c.1128C>G p.C376W | Missense Mutation (SNP) | VAF 38/732 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV53034718; called by muse, mutect2
- OR5M10 | c.812C>A p.S271Y | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101595935; called by muse, mutect2, varscan2
- POFUT2 | c.683A>G p.Y228C | Missense Mutation (SNP) | VAF 26/331 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs141027105; called by muse, mutect2
- PRKACG | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 30/532 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs867924490, COSV55245899; called by muse, mutect2
- SYNE1 | c.2662G>A p.V888M (on ENST00000367255 / NM_182961.4; = p.V895M on NM_033071.3) | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as rs756888254; called by muse, mutect2
- ZNF716 | c.571G>T p.G191C | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101348673, COSV70781667; called by muse, mutect2
- ABCC8 | c.2041-1G>T p.X681_splice | Splice Site (SNP) | VAF 26/332 reads (8%) | called by muse, mutect2
- AOC1 | c.1897T>C p.C633R | Missense Mutation (SNP) | VAF 23/359 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2
- ATP1A3 | c.2753A>G p.E918G (on ENST00000545399 / NM_001256214.2; = p.E905G on NM_152296.5) | Missense Mutation (SNP) | VAF 66/804 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CACNA1D | c.4017G>T p.L1339F (on ENST00000350061 / NM_001128840.3; = p.L1359F on NM_000720.4) | Missense Mutation (SNP) | VAF 21/257 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- CCNB3 | c.3210G>C p.K1070N | Missense Mutation (SNP) | VAF 20/261 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.011); called by muse, mutect2
- CDH23 | c.557T>C p.I186T | Missense Mutation (SNP) | VAF 16/327 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.027); called by muse, mutect2
- CDKAL1 | c.1483G>T p.A495S | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- CFAP69 | c.2215G>A p.A739T | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.015); called by muse, mutect2
- CNGA3 | c.698T>C p.V233A | Missense Mutation (SNP) | VAF 15/263 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- DCXR | c.538A>T p.T180S | Missense Mutation (SNP) | VAF 20/364 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- DDC | c.59A>G p.Y20C | Missense Mutation (SNP) | VAF 50/654 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DDIAS | c.1279G>T p.A427S | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2
- DIP2A | c.1382A>T p.Q461L | Missense Mutation (SNP) | VAF 37/354 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DPEP3 | c.941A>T p.N314I | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2
- EGFLAM | c.1548del p.S517Afs*24 | Frame Shift Del (DEL) | VAF 22/186 reads (12%) | called by mutect2, pindel, varscan2
- GGA2 | c.177-8C>T | Splice Region (SNP) | VAF 24/303 reads (8%) | called by muse, mutect2
- HDC | c.1044C>A p.H348Q | Missense Mutation (SNP) | VAF 26/532 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- HMCN1 | c.14159C>G p.A4720G | Missense Mutation (SNP) | VAF 27/494 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.089); called by muse, mutect2
- HNF4G | c.842C>A p.S281Y (on ENST00000354370 / NM_001330561.2; = p.S328Y on NM_004133.5) | Missense Mutation (SNP) | VAF 30/532 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- IL23R | c.1610T>C p.V537A | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.036); called by muse, mutect2
- INHBA | c.988T>G p.F330V | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IQGAP1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 20/474 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); called by muse, mutect2
- LCE2A | c.65C>A p.P22H | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.54); called by muse, mutect2
- MUC4 | c.14084G>C p.G4695A (on ENST00000463781 / NM_018406.7; = p.G459A on NM_004532.6) | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- PIWIL2 | c.907A>T p.S303C | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASA1 | c.2848G>T p.E950* | Nonsense Mutation (SNP) | VAF 14/285 reads (5%) | called by muse, mutect2
- SMARCA1 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 17/157 reads (11%) | called by muse, mutect2, varscan2
- STAB2 | c.2210G>T p.C737F | Missense Mutation (SNP) | VAF 12/275 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- STK32B | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.26); called by muse, mutect2
- TBL1X | c.428T>G p.V143G | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); called by muse, varscan2
- TEK | c.2930T>C p.V977A | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.074); called by muse, mutect2
- TENM4 | c.5978C>A p.T1993N | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- TNR | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.338); called by muse, mutect2
- TWSG1 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 18/306 reads (6%) | called by muse, mutect2
- USH2A | c.704C>A p.T235K | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2
- VCAN | c.9794G>C p.C3265S | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WNT8A | c.277T>A p.S93T | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.745); called by muse, mutect2
- ZFHX4 | c.7160C>A p.T2387N | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.049); called by muse, mutect2
- AHNAK2 | c.8994G>A p.E2998= | Silent (SNP) | VAF 58/646 reads (9%) | called by muse, mutect2
- CYP2D6 | c.339G>C p.G113= | Silent (SNP) | VAF 44/597 reads (7%) | called by muse, mutect2
- FAM90A10P | c.1125C>A p.A375= | Silent (SNP) | VAF 36/578 reads (6%) | catalogued as rs1353864203; called by muse, mutect2
- FBN2 | c.6540C>A p.G2180= | Silent (SNP) | VAF 38/383 reads (10%) | called by muse, mutect2, varscan2
- HECTD3 | c.483C>A p.L161= | Silent (SNP) | VAF 16/331 reads (5%) | catalogued as COSV55799822; called by muse, mutect2
- IMPG1 | c.348C>T p.R116= | Silent (SNP) | VAF 18/162 reads (11%) | called by muse, mutect2, varscan2
- ITPRID1 | c.2328C>G p.P776= | Silent (SNP) | VAF 33/296 reads (11%) | catalogued as COSV60073880; called by muse, mutect2, varscan2
- KALRN | c.1362C>T p.I454= | Silent (SNP) | VAF 9/252 reads (4%) | called by muse, mutect2
- MPEG1 | c.1218C>T p.L406= | Silent (SNP) | VAF 21/191 reads (11%) | called by muse, mutect2, varscan2
- MTMR14 | c.1320C>T p.T440= | Silent (SNP) | VAF 32/512 reads (6%) | called by muse, mutect2
- NLRP2 | c.1794G>T p.T598= | Silent (SNP) | VAF 24/662 reads (4%) | called by muse, mutect2
- OSBPL11 | c.1344A>G p.P448= | Silent (SNP) | VAF 18/324 reads (6%) | catalogued as rs1197240733; called by muse, mutect2
- SPATA31A6 | c.3459T>C p.P1153= | Silent (SNP) | VAF 44/757 reads (6%) | catalogued as rs762573927; called by muse, mutect2
- SPTBN4 | c.6219C>T p.S2073= | Silent (SNP) | VAF 20/196 reads (10%) | called by muse, mutect2
- TM2D3 | c.666G>T p.L222= (on ENST00000333202 / NM_078474.3; = p.L196= on NM_025141.3) | Silent (SNP) | VAF 15/233 reads (6%) | called by muse, mutect2
- TMEM121B | c.1173C>A p.R391= | Silent (SNP) | VAF 28/559 reads (5%) | catalogued as rs1434152366; called by muse, mutect2
- TMEM42 | c.33C>T p.A11= | Silent (SNP) | VAF 7/105 reads (7%) | catalogued as COSV56643764; called by muse, mutect2
- CYP19A1 | c.*480G>T | 3'UTR (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- DIP2C | c.85+38301G>A | Intron (SNP) | VAF 15/467 reads (3%) | called by muse, mutect2
- DNAJC19 | c.-102G>T | 5'UTR (SNP) | VAF 25/498 reads (5%) | called by muse, mutect2
- EIPR1 | c.516+5238G>T | Intron (SNP) | VAF 8/57 reads (14%) | catalogued as rs1458738049; called by muse, varscan2
- GFM1 | c.81+18G>T | Intron (SNP) | VAF 24/397 reads (6%) | catalogued as rs1377938684; called by muse, mutect2
- KIAA0586 | c.366-2555A>T | Intron (SNP) | VAF 9/203 reads (4%) | catalogued as COSV99707319; called by muse, mutect2
- LINC00602 | n.597C>A | RNA (SNP) | VAF 36/428 reads (8%) | called by muse, mutect2
- LINC00602 | n.598C>A | RNA (SNP) | VAF 38/432 reads (9%) | catalogued as rs1562345517; called by muse, mutect2
- MED14 | chrX:40735655 C>T | 5'Flank (SNP) | VAF 20/175 reads (11%) | called by muse, mutect2, varscan2
- NEB | c.2310+70C>A | Intron (SNP) | VAF 9/144 reads (6%) | catalogued as COSV51420135; called by muse, mutect2
- NUP160 | c.*74A>T | 3'UTR (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- RELB | c.155-1303G>A | Intron (SNP) | VAF 24/211 reads (11%) | called by muse, mutect2, varscan2
